Surgical pathology report (de-identified scan), TCGA case TCGA-PC-A5DL, project TCGA-SARC (Sarcoma), tissue source site Fox Chase, specimen TCGA-PC-A5DL-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN:
SURGICAL PATHOLOGY REPORT

DOB
Sex: M
Location:
Date Collected:
Date Received
Physician:
Copy To:
Clinical History/Diagnosis: Sarcoma.

ICD-O-3
1103
Neuromyosarcoma 8890/3
Site: Retroperitoneum 048.0
JW 5/24/13

Source of Specimen(s):
A: Micro
B: Micro
C: Liver, lesion segment 4 biopsy
D: sarcoma, retroperitoneal
E: Appendix

Gross Description:
Received in five parts.

Source of Tissue: 1. Microbiology.

Source of Tissue: 2. Microbiology.

Source of Tissue: 3. Labeled #3 "liver lesion segment #4"

Frozen Section Diagnosis: 3FS BILE DUCT HAMARTOMA/ADENOMA PER

Gross Description: The specimen is received fresh for frozen section consultation in a container labeled with the patient's name designated "liver lesion segment #4" and consists of a single fragment of tan and brown soft tissue measuring 0.3 x 0.3 x 0.3 cm. Entirely submitted and sectioned and the residue is submitted in 3FS.

Source of Tissue: 4. Labeled #4 "retroperitoneal sarcoma"

Gross Description: The specimen is received fresh in a container labeled with the patient's name designated "retroperitoneal sarcoma" and consists of an ovoid rubbery mass weighing 263 gm and measuring 11 x 7.5 x 6.5 cm. Externally, it is encapsulated. Sections disclose a tan homogeneous rubbery to firm whorling cut surface. Centrally, there is one area of yellow discoloration with some fat necrosis and may represent previous biopsy site (4D).

[page 2 of 2]
Designation of Sections: Representative sections are submitted in 4A-4E

Source of Tissue: 5. Labeled #5 "appendix"

Gross Description: The specimen is received fresh in a container labeled with the patient's name designated "appendix" and consists of a vermiform appendix measuring 6.7 x 0.9 x 0.8 cm with a mesoappendix measuring up to 2 cm from point of attachment. Externally, the appendix is pink and smooth. Sections disclose a patent lumen containing some clear to yellow thin fluid. No fecalith or suspicious lesions or masses are identified.

Representative sections are submitted in 5A.

Final Diagnosis:

1. Microbiology Specimen
2. Microbiology Specimen
3. Liver, segment 4 (biopsy):
- Von Meyenburg complex (bile duct hamartoma).
4. Retroperitoneal soft tissue (excision):
- Intermediate grade leiomyosarcoma (11 cm) with focal necrosis.
- Inked margins are free of tumor.
5. Appendix (appendectomy):
- Appendix with non-specific chronic inflammation.

Note: Immunohistochemical staining shows the tumor cells are positive for SMA, vimentin and desmin and negative for HMB45. These results are supportive of the diagnosis of leiomyosarcoma.

These tests were developed and their performance characteristics determined by the immunohistochemistry laboratory at the

These tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1998 (CLIA) as qualified to perform high complexity clinical testing.

Source: NCI Genomic Data Commons file 05c2056a-7a8b-499a-8706-8014e5e061e5 (TCGA-PC-A5DL.F6495C96-BCFD-4C3B-AE01-E196A75FB31B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).